Somatic mutation profile of tumor specimen SM-JU34Q (aliquot 7316UP-243) from CPTAC case C247230, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G4.
Specimen SM-JU34Q: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11e5214c-1f21-4db3-8428-b88443c36ca0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105280 (Blood Derived Normal), aliquot 7316UP-243-1105280; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce3b9a89-8636-428e-8524-516a3a11a3b3

The open-access MAF lists 36 somatic variants for this specimen: 19 protein-altering or splice-affecting, 13 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 13, Nonsense Mutation 2, Intron 2, 5'Flank 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA2D4 | c.2587C>T p.R863C | Missense Mutation (SNP) | VAF 20/330 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as rs775588255; ClinVar: uncertain significance; called by muse, mutect2
- CCDC6 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.338); catalogued as COSV54055823; called by muse, mutect2, varscan2
- CHGB | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.744); catalogued as rs373817587, COSV100972942; called by muse, mutect2
- CYP2C18 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 32/249 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767161951; called by muse, mutect2, varscan2
- GBA | c.308G>A p.G103D | Missense Mutation (SNP) | VAF 24/343 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.019); catalogued as rs748485792, CM140309, COSV59169558; called by muse, mutect2
- GGT6 | c.526G>A p.G176S (on ENST00000574154 / NM_001122890.3; = p.G144S on NM_153338.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as rs777856032; called by muse, mutect2
- IGHM | c.1402G>A p.V468I | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as rs772304630; called by muse, mutect2
- LAD1 | c.566C>T p.T189M | Missense Mutation (SNP) | VAF 12/163 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs370468944; called by muse, mutect2
- RYR1 | c.6445G>A p.V2149M | Missense Mutation (SNP) | VAF 27/490 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as rs776830747, COSV62109696; ClinVar: uncertain significance; called by muse, mutect2
- SUDS3 | c.961G>A p.V321M | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.538); catalogued as COSV64349096; called by muse, mutect2
- VPS13D | c.3943C>T p.R1315* | Nonsense Mutation (SNP) | VAF 27/208 reads (13%) | catalogued as rs1014084562, COSV50691564; called by muse, mutect2, varscan2
- GIGYF2 | c.2326G>T p.E776* | Nonsense Mutation (SNP) | VAF 22/320 reads (7%) | called by muse, mutect2
- MLLT3 | c.295C>G p.R99G | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.961); called by muse, mutect2
- MYO1H | c.1142C>T p.S381F | Missense Mutation (SNP) | VAF 11/190 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- NCOA2 | c.2693G>C p.G898A | Missense Mutation (SNP) | VAF 21/372 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2
- PTEN | c.55del p.D19Mfs*5 | Frame Shift Del (DEL) | VAF 34/335 reads (10%) | called by mutect2, pindel, varscan2
- SLC25A52 | c.409C>T p.L137F (on ENST00000672005; = p.L127F on NM_001034172.4) | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.209); called by muse, mutect2
- TMPRSS11B | c.98G>T p.G33V | Missense Mutation (SNP) | VAF 10/225 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- USH2A | c.1099C>A p.Q367K | Missense Mutation (SNP) | VAF 6/143 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0.089); called by muse, mutect2
- ADGRG4 | c.5910C>T p.D1970= | Silent (SNP) | VAF 7/80 reads (9%) | catalogued as rs760543724, COSV54949082; called by muse, mutect2
- ANK1 | c.1866G>A p.L622= | Silent (SNP) | VAF 28/440 reads (6%) | catalogued as rs776247811; called by muse, mutect2
- ARSH | c.321C>T p.G107= | Silent (SNP) | VAF 7/74 reads (9%) | called by muse, mutect2
- ASXL1 | c.1830C>T p.G610= | Silent (SNP) | VAF 19/356 reads (5%) | catalogued as rs199829982; called by muse, mutect2
- CCDC8 | c.516C>T p.R172= | Silent (SNP) | VAF 12/282 reads (4%) | catalogued as rs1249316819, COSV56772484; called by muse, mutect2
- CTH | c.1080T>G p.L360= | Silent (SNP) | VAF 15/275 reads (5%) | called by muse, mutect2
- DAW1 | c.1197C>T p.G399= | Silent (SNP) | VAF 13/109 reads (12%) | called by muse, mutect2, varscan2
- KRT19 | c.723G>A p.P241= | Silent (SNP) | VAF 16/254 reads (6%) | catalogued as rs140667731; called by muse, mutect2
- OXSR1 | c.264G>A p.L88= | Silent (SNP) | VAF 12/284 reads (4%) | catalogued as COSV61259203; called by muse, mutect2
- PCDHGB3 | c.1869G>A p.T623= | Silent (SNP) | VAF 17/242 reads (7%) | catalogued as COSV53937747; called by muse, mutect2
- SLC27A2 | c.831C>T p.H277= | Silent (SNP) | VAF 13/141 reads (9%) | catalogued as rs79765607; called by muse, mutect2
- TMEM147 | c.481C>T p.L161= | Silent (SNP) | VAF 28/283 reads (10%) | called by muse, mutect2
- USH2A | c.14073C>T p.N4691= | Silent (SNP) | VAF 12/194 reads (6%) | catalogued as rs370364142, COSV56342993; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2
- ACADVL | c.*51G>C | 3'UTR (SNP) | VAF 9/230 reads (4%) | called by muse, mutect2
- ANKRD18A | chr9:38621264 G>C | 5'Flank (SNP) | VAF 19/298 reads (6%) | catalogued as rs1457530152; called by muse, mutect2
- LGI4 | c.1300-233C>T | Intron (SNP) | VAF 7/81 reads (9%) | called by muse, mutect2
- NADSYN1 | c.146+9A>G | Intron (SNP) | VAF 10/72 reads (14%) | called by muse, mutect2, varscan2
